Somatic mutation profile of tumor specimen TCGA-DD-AAD3-01A (aliquot TCGA-DD-AAD3-01A-11D-A40R-10) from TCGA case TCGA-DD-AAD3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 43.0 years (15,706 days).
Specimen TCGA-DD-AAD3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61791b77-703b-43b5-9ed4-81c0daf2af1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAD3-10A (Blood Derived Normal), aliquot TCGA-DD-AAD3-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d956a2e0-5e42-4384-b694-1810d1efdf17

The open-access MAF lists 79 somatic variants for this specimen: 56 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 21, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, 3'Flank 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM942136, COSV52661418, COSV52925998, COSV53589174; called by muse, mutect2, varscan2
- ADAD2 | c.806G>A p.C269Y (on ENST00000315906 / NM_001145400.2; = p.C351Y on NM_139174.4) | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0.063); catalogued as rs749009923, COSV99235034; called by muse, mutect2, varscan2
- ADH5 | c.343A>T p.R115* | Nonsense Mutation (SNP) | VAF 121/284 reads (43%) | catalogued as COSV99596089; called by muse, mutect2, varscan2
- ALG10B | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100439768; called by muse, mutect2, varscan2
- ANO4 | c.625T>C p.F209L (on ENST00000392977 / NM_001286615.2; = p.F174L on NM_178826.4) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100151749; called by muse, mutect2, varscan2
- B4GALT2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1312790665, COSV100530561; called by muse, mutect2, varscan2
- BMP6 | c.1206T>C p.D402= | Splice Region (SNP) | VAF 47/164 reads (29%) | catalogued as rs774591705, COSV99306275; called by muse, mutect2, varscan2
- BRIP1 | c.1811A>G p.N604S | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.182); catalogued as COSV99369162; called by muse, mutect2, varscan2
- C1orf131 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 16/254 reads (6%) | catalogued as COSV100009485; called by muse, mutect2
- CCDC89 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320800; called by muse, mutect2, varscan2
- ELP1 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100534589; called by muse, mutect2, varscan2
- ELP4 | c.949C>T p.R317C (on ENST00000350638; = p.R316C on NM_019040.5) | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs764805051, COSV100635078, COSV100635774; called by muse, mutect2, varscan2
- EP300 | c.2384A>G p.Q795R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as COSV99607223; called by muse, mutect2, varscan2
- ERBB4 | c.1594T>C p.C532R | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99615745; called by muse, mutect2, varscan2
- FAM163A | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100522870; called by muse, mutect2, varscan2
- FAT4 | c.4999A>G p.I1667V | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0.245); catalogued as COSV101271812; called by muse, mutect2, varscan2
- FBXO42 | c.388A>G p.N130D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV100981622; called by muse, mutect2, varscan2
- GGCX | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.017); catalogued as COSV99289623; called by muse, mutect2, varscan2
- GPR108 | c.1034C>G p.T345S (on ENST00000264080 / NM_001080452.1; = p.T103S on NM_020171.2) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99901124; called by muse, mutect2
- GPR78 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV66762930; called by muse, mutect2, varscan2
- GRIA4 | c.1125T>G p.D375E | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as COSV56884487, COSV99228584; called by muse, mutect2, varscan2
- HSH2D | c.691T>A p.S231T | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as rs1426993225, COSV99507048; called by muse, mutect2, varscan2
- ICE2 | c.2878A>G p.K960E | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV99831253; called by muse, mutect2, varscan2
- IDE | c.1487A>G p.Y496C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372524227, COSV99793752; called by muse, mutect2, varscan2
- IMPG2 | c.3670G>T p.A1224S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99514683; called by muse, mutect2, varscan2
- LRAT | c.310A>C p.K104Q | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100311989; called by muse, mutect2, varscan2
- LRCH3 | c.1993-2A>G p.X665_splice | Splice Site (SNP) | VAF 56/220 reads (25%) | catalogued as COSV100604936; called by muse, varscan2
- LRIT1 | c.1071C>G p.S357R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as COSV100927992; called by muse, mutect2, varscan2
- MAGI2 | c.2675C>A p.T892N | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs780033666, COSV100832495; called by muse, mutect2, varscan2
- MAOB | c.142-1G>T p.X48_splice | Splice Site (SNP) | VAF 25/55 reads (45%) | catalogued as COSV100955883; called by muse, mutect2, varscan2
- NLGN4X | c.1143C>A p.D381E | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52042984, COSV99319681; called by muse, mutect2, varscan2
- NOTCH4 | c.1910A>C p.K637T | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as COSV100900330; called by muse, mutect2, varscan2
- PCDHB5 | c.1840T>C p.F614L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99167603; called by muse, mutect2, varscan2
- PDE3A | c.2508C>A p.H836Q | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100761609, COSV62979973; called by muse, mutect2, varscan2
- PPP1R36 | c.733T>G p.Y245D | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100072662; called by muse, mutect2, varscan2
- PTAR1 | c.979A>G p.N327D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.006); catalogued as COSV100466290; called by muse, mutect2, varscan2
- RANBP9 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99163491; called by muse, mutect2, varscan2
- RGS7 | c.1089G>C p.W363C | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100464292, COSV100471289; called by muse, mutect2, varscan2
- SALL3 | c.1078A>G p.S360G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV101609924; called by muse, mutect2, varscan2
- SI | c.1458G>C p.W486C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100013775; called by muse, mutect2, varscan2
- SLC39A7 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771311186, COSV100761714; called by muse, mutect2, varscan2
- SLC7A4 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100298503; called by muse, mutect2, varscan2
- SNTB2 | c.1500C>A p.Y500* | Nonsense Mutation (SNP) | VAF 53/122 reads (43%) | catalogued as COSV100292981; called by muse, mutect2, varscan2
- SPTB | c.3744G>C p.K1248N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67629998; called by muse, mutect2, varscan2
- STAT6 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100273047; called by muse, mutect2, varscan2
- TIGD4 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV100427867, COSV58550563; called by muse, mutect2, varscan2
- TINAG | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99448392; called by muse, mutect2
- TJAP1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99035690, COSV99446115; called by muse, mutect2, varscan2
- TLL2 | c.2515G>A p.G839R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs141213956; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1073A>G p.K358R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV100708862, COSV61455067; called by muse, mutect2, varscan2
- UNC13C | c.2045G>C p.S682T | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.15); catalogued as COSV52928126, COSV99511140, COSV99512516; called by muse, mutect2, varscan2
- ZCWPW2 | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 117/366 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs751684863, COSV101074488; called by muse, mutect2, varscan2
- ZNF804B | c.1906A>G p.K636E | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100301588; called by muse, mutect2, varscan2
- DCAF1 | c.814del p.Q272Rfs*40 | Frame Shift Del (DEL) | VAF 36/141 reads (26%) | called by mutect2, pindel, varscan2
- KCNN4 | c.1042del p.I348Sfs*9 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- MYO9B | c.6266_6267del p.E2089Gfs*110 | Frame Shift Del (DEL) | VAF 41/165 reads (25%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.2175C>T p.F725= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs1555849813, COSV100528832; called by muse, mutect2, varscan2
- BARHL2 | c.714T>A p.A238= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV100966013; called by muse, mutect2
- CYP4A22 | c.1344G>T p.L448= | Silent (SNP) | VAF 46/181 reads (25%) | catalogued as COSV99594563; called by muse, mutect2, varscan2
- DCTN1 | c.1485G>T p.R495= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV100720856, COSV100721127; called by muse, mutect2, varscan2
- DDX4 | c.795C>A p.G265= | Silent (SNP) | VAF 59/204 reads (29%) | catalogued as COSV100737278; called by muse, mutect2, varscan2
- GALR2 | c.1092C>T p.L364= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100134809, COSV57164470; called by muse, mutect2
- GON4L | c.33G>T p.V11= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as COSV99673194; called by muse, mutect2, varscan2
- HBA1 | c.372C>T p.A124= | Silent (SNP) | VAF 17/248 reads (7%) | catalogued as COSV99285346; called by muse, mutect2
- KAT6B | c.4587G>A p.E1529= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV99767275; called by muse, mutect2, varscan2
- LTBP4 | c.1431A>G p.R477= (on ENST00000308370 / NM_001042544.1; = p.R440= on NM_003573.2) | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV99180360; called by muse, mutect2, varscan2
- MAGI2 | c.2676C>A p.T892= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV100832494; called by muse, mutect2
- MAPT | c.1815G>A p.P605= (on ENST00000262410 / NM_001377265.1; = p.P213= on NM_005910.5) | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs201157234, COSV99289664; called by muse, mutect2, varscan2
- OR9K2 | c.54A>G p.Q18= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV59532383; called by muse, mutect2, varscan2
- PLK2 | c.1890A>G p.T630= | Silent (SNP) | VAF 45/161 reads (28%) | catalogued as COSV57109921, COSV99955764; called by muse, mutect2, varscan2
- PPP1R3A | c.2553C>T p.V851= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as COSV99491849; called by muse, mutect2, varscan2
- PXDNL | c.3676C>T p.L1226= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV100680982, COSV100686399; called by muse, mutect2, varscan2
- RNH1 | c.516C>T p.F172= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1351482088, COSV100596640; called by muse, mutect2, varscan2
- SRCAP | c.756C>T p.N252= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV99349164; called by muse, mutect2, varscan2
- STBD1 | c.987G>T p.G329= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as COSV99421369; called by muse, mutect2, varscan2
- TMEM54 | c.249C>A p.R83= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100231839; called by muse, mutect2
- ZSWIM1 | c.324T>A p.L108= | Silent (SNP) | VAF 54/169 reads (32%) | catalogued as COSV99666070; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701237 C>A | 3'Flank (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2
- TMEM183B | n.994G>C | RNA (SNP) | VAF 97/337 reads (29%) | called by muse, mutect2, varscan2
